Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5877, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5877-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

None-given.

Specimens Submitted:

1: SP: Kidney, left, radical nephrectomy [REDACTED]

2: SP: Lymph node, para-aortic, excision [REDACTED]

DIAGNOSIS:

1. SP: Kidney, left, radical nephrectomy [REDACTED]

Tumor Type:

Renal cell carcinoma - Papillary type
with sarcomatoid component.

Fuhrman Nuclear Grade:

High nuclear grade

Tumor Size:

Greatest diameter is 3 cm.

The tumor is multinodular, the largest node measures up to 3 cm in greatest diameter.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia
Involves renal sinus fat

Renal Vein Invasion:

Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Number of metastatic nodes:1

Number of nodes examined:1

Staging for renal cell carcinoma/oncocytoma:

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

Comment:

[REDACTED] reviewed the case and concurs with the diagnosis.

[page 2 of 3]
2. SP: Lymph node, para-aortic, excision

Lymph Nodes:

Number of nodes examined:1
Number of metastatic nodes:1
The largest metastatic node is 3.0cm
Perinodal (extracapsular) extension identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	

Gross Description:

1) The specimen is received fresh, labeled, "Left kidney". It consists of a radical nephrectomy specimen measuring 22.0 x 10.0 x 3.7 cm and weighing 557 grams. Sectioning reveals kidney measuring 13.0 x 7.5 x 3.0 cm. No adrenal gland is grossly identified. Segment of unremarkable ureter is noted, measuring 3.0 x 0.6 cm. The ureteral and vascular margins appear grossly negative and are sampled. The renal parenchyma reveals at the superior pole, a well circumscribed, multinodular, tan-gray, rubbery tumor, measuring 3.0 x 3.0 x 1.8 cm. Departing from the tumor and descending into the mid-portion of kidney and renal pelvic fat are other multiple smaller nodules, ranging in dimensions from 0.3 to 1.7 cm. Some smaller nodules reveal a tan-yellow soft friable cut surface. Some nodules appear to be included within the renal pelvic fat. The renal pelvic and calyceal system appears negative for lesions. The rest of the renal parenchyma reveals a well-defined cortical medullary junction with preserved architecture. Sectioning through hilar fat reveals no lymph nodes. Representative sections are taken. Section is taken for TPS and electron microscopy.

Summary of Sections:

MARG – margin
TM – tumor
TMNS – tumor nodules
NORM – normal kidney
HYL – representative hilar fat
TMPELF- tumor and pelvic fat
NORMPEL – normal pelvis

2) The specimen is received in formalin, labeled, "Para-aortic lymph node". It consists of a pink-tan rubbery lymph node measuring 3.0 x 1.6 x 1.5 cm. Sectioning of the specimen reveals an indurated, tan-gray, cut surface, grossly suspicious for tumor. Representative section taken.

Summary of Sections:

LN - lymph node

Summary of Sections:

Part 1: SP: Kidney, left, radical nephrectomy

Block	Sect. Site	PCs
2	HYL	2
1	MARG	1

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

2	NORM	2
1	NORMPEL	1
5	TM	5
3	TMNS	3
1	TMPELF	1

Part 2: SP: Lymph node, para-aortic, excision [REDACTED]

Block	Sect. Site	PCs
2	LN	2

Source: NCI Genomic Data Commons file fab14834-4513-45ae-ac50-d26d2908b51e (TCGA-BQ-5877.314F46D4-62C8-4A2D-AFD6-E2188D10E316.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).